Surgical pathology report (de-identified scan), TCGA case TCGA-OR-A5LF, project TCGA-ACC (Adrenocortical Carcinoma), tissue source site University of Michigan, specimen TCGA-OR-A5LF-01A (Primary Tumor).

Procedure: L adrenalectomy and splenectomy

Gross description: 11 x 10 x 6cm, tumor 7 x 5.5 x 5cm, 155g

Diagnosis: adrenocortical carcinoma, G2

Reference Pathology:

Diagnosis: adrenocortical carcinoma, KI67 not evaluable

Weiss score: 5

Hough score: 1.89

Van Slooten score: 12.3

ICD-O-3

Carcinoma, adrenal cortical
8370/3

Site ④ Adrenal Gland Cortex
074.0

gnd 2/6/13

Discrepancy		
Histologic Discrepancy		
Reviewed Initials	1/14/13	

Source: NCI Genomic Data Commons file c58cba9c-3c9b-4498-ada2-eb5d42808ae0 (TCGA-OR-A5LF.1E988E48-9FF4-4355-89CE-410CC1964D6C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).